Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A0YD, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A0YD-01A (Primary Tumor).

[page 1 of 2]
100-0-3

Carcinoma, infiltrating lobular 85201

Site: breast, Nos C50.9

1/27/11

SURGICAL REPORT

Name:

Sex: F

DOB:

Location:

Doctor:

Pathology Number

Date Collected:

Date Received:

M.R. Number:

Account Number:

PRE-OPERATIVE DIAGNOSIS

LEFT BREAST CANCER

POST-OPERATIVE DIAGNOSIS

LEFT BREAST CANCER

PROCEDURE

LEFT BREAST TOTAL MASTECTOMY WITH SENTINEL LYMPH NODE BIOPSY, F.S.

TISSUES

- A. LYMPH NODE (S) - LEFT SENTINEL LYMPH NODE #1 **FS**
- B. LYMPH NODE (S) - LEFT SENTINEL LYMPH NODE #2 **FS**
- C. BREAST MASTECTOMY (WWO) NODES - LEFT

WRI TISSUE

FS DIAGNOSIS

- A. LEFT SENTINEL LYMPH NODE #1, F.S. -
NEGATIVE (0/1).
- B. LEFT SENTINEL LYMPH NODE #2, F.S. -
NEGATIVE (0/1).

(Reported to surgeon:

Diagnosed by:

FINAL DIAGNOSIS

- A. LEFT SENTINEL LYMPH NODE #1 -
ONE (1) BENIGN REACTIVE REGIONAL LYMPH NODE, NEGATIVE FOR
MALIGNANCY.
- B. LEFT SENTINEL LYMPH NODE #2 -
ONE (1) BENIGN REACTIVE REGIONAL LYMPH NODE, NEGATIVE FOR
MALIGNANCY.
- C. LEFT BREAST MASTECTOMY -
MODERATELY DIFFERENTIATED INFILTRATING LOBULAR CARCINOMA, 6.5 CM., WITH
FOCI OF LOBULAR CARCINOMA IN-SITU INVOLVING TERMINAL
DUCTULES.

SCARFF-BLOOM-RICHARDSON BREAST CANCER HISTOLOGIC SCORE 6 (3+2+1).

ALL DESIGNATED INKED SURGICAL MARGINS ARE FREE OF TUMOR.

Patient Name:

Pathology Number:

SURGICAL REPORT

RECEIVED

Page 1 of 2

[page 2 of 2]
Patient Name:

Pathology Number

PATHOLOGIC TNM STAGE: T3 PN0(I+) MX, STAGE IIB, G2, INFILTRATING LOBULAR CARCINOMA.

PQRI CATEGORY II: 3260F.

Diagnosed by

Reviewed and electronically signed out by:

COMMENT

The immunohistochemical stains on the first sentinel lymph node (specimen A) reveals seven positive cells with the Cytokeratin stain in the subcapsular space indicating incidental microscopic micrometastases. The seven cells are in total measurements less than 0.1 mm. The second lymph node (specimen B) is negative. No individual positive cells seen.

GROSS DESCRIPTION

The specimen is received in three separate containers labeled designated A, B, C.

- A. The container is received fresh unfixed labeled "left sentinel lymph node #1 for frozen section". The specimen consists of an ovoid mass of apparent fatty tissue which is 1 x 0.4 x 0.3 cm. in greatest overall dimension. Sectioning reveals a pink-tan firm nodule varying up to 0.4 cm. in greatest dimension. Touch prep and frozen section are obtained by Dr. The entire specimen including frozen section is submitted in two blocks.
- B. The container is received fresh unfixed labeled "left sentinel lymph node #2 for frozen section" and consists of an ovoid mass of apparent fatty tissue which is 0.4 x 0.3 x 0.3 cm. The specimen is bisected revealing a thin rim of pink-tan firm tissue. Frozen section and touch prep are obtained by The entire specimen including frozen section is submitted in two blocks.
- C. The container is received fresh unfixed labeled "left breast - suture on upper outer quadrant" and consists of an 953 gm. apparent left breast which is 23 x 20 x 5 cm. in greatest overall dimension. There is an attached suture indicating upper outer quadrant which is inked with yellow dye. The lower outer quadrant is inked with an orange dye. The upper inner quadrant is inked with red dye, and the lower inner is inked with green dye. Serial sectioning reveals a firm tan-gray tumor mass which is 6.5 x 4.5 x 3 cm. in greatest overall dimension and grossly appears to be 2 cm. from the underlying resection line, 5.5 cm. from the lower outer quadrant, 7 cm. from the upper inner, 8 cm. from the lower inner and 8 cm. from the upper outer. The specimen is submitted in nine blocks.

Key Note Block Summary: 1—nipple, 2 through 4—tumor, 5—deep resection line, 6—upper inner, 7—upper outer, 8—lower inner, 9—lower outer.

MICROSCOPIC EXAM

MICROSCOPIC EXAMINATION CONDUCTED BY PATHOLOGIST CONFIRMS FINAL DIAGNOSIS.

SPECIAL STAINS PERFORMED: PanKeratin (specimens A & B) (CG)

Patient Name

SURGICAL REPORT

Pathology Number: _____

Page 2 of 2

Source: NCI Genomic Data Commons file 73c36f00-7388-48fe-8c6d-9fa68354d181 (TCGA-A2-A0YD.10DA3573-BD53-4579-AD90-E770CEF08498.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).